Gene-level copy-number profile of tumor specimen TCGA-EE-A180-06A from TCGA case TCGA-EE-A180, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.1 years (28,165 days).
Specimen TCGA-EE-A180-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.21dbd59c-803f-46ab-84d3-642962912c8e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A180-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40c6553d-3e89-4dc8-8116-a04313b96b5a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,481; copy number 2: 27,670; copy number 3: 24,503; copy number 4: 2,667; copy number 5: 1,837; copy number 6: 12; copy number 9: 556; copy number 19: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A180-06A-11D-A219-01): tumor purity 0.92, ploidy 2.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,499 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,367,449–151,348,027, 406 genes, copy number 5–19 (within-gene range 2–19) (broad region; genes not listed).
- chr1:217,426,992–248,919,946, 736 genes, copy number 5–9 (broad region; genes not listed).
- chr13:18,467,172–32,538,885, 327 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:32,586,452–32,954,401, 5 genes, copy number 5 (within-gene range 4–5): PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3.
- chr13:33,103,137–35,673,022, 29 genes, copy number 5: STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1, AL139081.2, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1.
- chr13:35,768,652–37,166,658, 27 genes, copy number 5: DCLK1, SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1, H2ACP1, SERTM1, GAPDHP34, TCEAL4P1, ARL2BPP3, NDE1P2, RFXAP, SMAD9, SMAD9-IT1, LAMTOR3P1, RPL29P28, EIF4A1P5, ALG5, EXOSC8, SUPT20H, CSNK1A1L, AL356274.1, AL356274.2, RN7SKP1.
- chr13:37,481,467–40,535,807, 35 genes, copy number 5–6 (within-gene range 4–6): LINC01048, LINC00547, POSTN, TRPC4, RNA5SP26, AL356495.1, LINC02334, HSPD1P9, LINC00571, UFM1, AL356863.1, LINC00437, LINC00366, PRDX3P3, FREM2, RNU6-56P, FREM2-AS1, PLA2G12AP2, ANKRD26P2, STOML3, PROSER1, NHLRC3, AL354809.1, NXT1P1, LHFPL6, COG6, MIR4305, RNY4P14, CDKN2AIPNLP3, AZU1P1, SNORD116, LINC00598, LINC00332, RPL17P51, RNY3P9.
- chr13:40,469,955–44,715,393, 89 genes, copy number 5 (broad region; genes not listed).
- chr13:44,939,249–90,135,841, 517 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:90,493,287–94,408,020, 31 genes, copy number 5–6 (within-gene range 3–6): LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6.
- chr13:93,394,977–94,596,242, 6 genes, copy number 5–6 (within-gene range 4–6): HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS.
- chr13:94,703,454–94,803,430, 1 gene, copy number 5 (within-gene range 4–5): SOX21-AS1.
- chr13:94,757,451–111,305,737, 236 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:111,588,201–112,108,015, 8 genes, copy number 5 (within-gene range 4–5): AL359649.1, LINC02337, LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404.
- chr13:112,313,467–112,331,225, 2 genes, copy number 5: LINC01043, LINC01044.
- chr13:112,647,044–113,887,149, 43 genes, copy number 5: ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2.
- chr13:114,107,569–114,108,820, 1 gene, copy number 5: RASA3-IT1.

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
